Somatic mutation profile of tumor specimen ALCH-B1XE-TTP1-A (aliquot ALCH-B1XE-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1XE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,424 days).
Specimen ALCH-B1XE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08ffd121-0956-4ee1-a764-34fd3ce1af92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XE-NB1-A (Blood Derived Normal), aliquot ALCH-B1XE-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e638d4ad-b1be-4280-8926-35b1b26b2a56

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2
- CNGB1 | c.2703G>A p.V901= | Silent (SNP) | VAF 12/352 reads (3%) | catalogued as rs1567369349; called by muse, mutect2
